Gene-level copy-number profile of specimen HCM-SANG-0544-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0544-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0544-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 96bcfd3d-89a8-49d5-8177-28d02227489d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0544-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/fa9a3a06-df78-40e1-b082-0ba5066cf34c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,802; copy number 2: 28,211; copy number 3: 23,234; copy number 4: 4,873; copy number 5: 664; copy number 6: 106.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,590,056–186,695,287, 2 genes (within-gene range 0–1): ITGAV, AC017101.1.
- chr6:32,552,713–32,560,022, 1 gene (within-gene range 0–1): HLA-DRB6.
- chr9:42,183,659–42,354,454, 5 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 770 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:7,287,924–7,326,609, 3 genes, copy number 5 (within-gene range 4–5): AC091951.2, AC091951.3, AC091951.1.
- chr5:38,258,409–38,465,480, 1 gene, copy number 5 (within-gene range 4–5): EGFLAM.
- chr5:38,399,814–41,895,599, 45 genes, copy number 5: EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1.
- chr5:43,287,470–43,313,512, 1 gene, copy number 5 (within-gene range 4–5): HMGCS1.
- chr5:43,336,164–45,098,647, 26 genes, copy number 5: AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1.
- chr8:12,310,962–12,665,588, 15 genes, copy number 5 (within-gene range 3–5): DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1.
- chr20:36,045,618–64,327,972, 672 genes, copy number 5–6 (broad region; genes not listed).
- chr21:10,482,738–13,016,692, 7 genes, copy number 5 (within-gene range 3–5): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.

Autosomal genes at a single copy (total copy number 1): 61. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
